Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A8GZ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-A8GZ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:

*Date - Date of Service:

Document Status:

Document Title:

Author:

Authenticated By:

Encounter info:

Contributor system:

* Final Report *

MICROSCOPIC EXAMINATION:

See final microscopic diagnosis

GROSS EXAMINATION:

The specimen is received fresh from the O.R. and labeled "Left testicle and spermatic cord". It consists of one testis with spermatic cord attached. The testis measures 6 x 4 x 2.5 cm. The spermatic cord measures 15 cm long and 1.2 cm in diameter. The entire specimen weighs 42 grams. Sectioning through the specimen reveals firm tan nodule, measuring 2.2 x 1.7 x 1.6 cm, located in the lower pole of the testicle. Representative sections are submitted in 18 cassettes.

SECTIONS:

A1: distal spermatic cord
A2: mid spermatic cord
A3: proximal spermatic cord
A4,5: epididymis and upper pole of the testis
A6-12: tumor
A13,14: B5 fixed tumor tissue
A15-18: normal testicular tissue

ICD-O-3

Seminoma NOS 9061/3

Site: ^{ICD-O-3} Testis NOS C62.9

① ^{ICD-O-3} Testicle NOS C62.9

QJ 11/24/13

Signature Line

CLINICAL INFORMATION:

Pre-Op Dx: Left testicular mass

Post-Op Dx: Same

SPECIMEN SOURCE:

Printed by:

Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

* Final Report *

"Left testicle and spermatic cord"

DIAGNOSIS:

LEFT TESTICLE AND SPERMATIC CORD:

- MULTIFOCAL SEMINOMA OF TESTIS (APPROXIMATELY 2.2 X 1.7 X 1.6 CM), CONFINED TO THE TESTICLE
- INTRATUBULAR GERM CELL NEOPLASIA IDENTIFIED
- SURGICAL MARGINS OF THE SPERMATIC CORD AND BLOOD VESSELS AT THE DISTAL, MIDDLE AND PROXIMAL SECTIONS, FREE OF MALIGNANCY
- NO LYMPHOVASCULAR INVASION IDENTIFIED
- EPIDIDYMIS, FREE OF MALIGNANCY
- ADJACENT TESTICULAR TUBULES SHOWING SEGMENTAL ATROPHY

PATHOLOGIC STAGE (AJCC 5TH EDITION): pTis, T1NXMX

Signature Line

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 20880fd0-da60-4ab9-994a-ca557bfe1c7a (TCGA-XE-A8GZ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).